Somatic mutation profile of tumor specimen 0DTHM9 from CCDI case PBCJXL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioneuroma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.8 years (4,664 days).
Specimen 0DTHM9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b9c9e84-8d25-43f8-984a-cfa5bb287778.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTHMF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a94841df-27ca-4adf-bd32-8299654e5bf0

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLB1L3 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 222/800 reads (28%) | catalogued as rs567099863; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 38/1290 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CHAT | c.1173C>T p.D391= | Silent (SNP) | VAF 152/475 reads (32%) | catalogued as rs141690626; called by muse, mutect2, varscan2
- MYO1E | c.1983G>A p.S661= | Silent (SNP) | VAF 179/650 reads (28%) | catalogued as rs753049686, COSV55684026; called by muse, mutect2, varscan2
